Gene-level copy-number profile of tumor specimen TCGA-AN-A0FJ-01A from TCGA case TCGA-AN-A0FJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.0 years (21,910 days).
Specimen TCGA-AN-A0FJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.84412819-5a7d-4d8c-a834-7170777e94e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4071b432-76db-4f1c-b978-bc03284b3b46

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 7; copy number 2: 19,579; copy number 3: 4,542; copy number 4: 27,039; copy number 5: 3,742; copy number 6: 3,893; copy number 7: 419; copy number 8: 120; copy number 9: 214; copy number 10: 60; copy number 11: 28; copy number 12: 1; copy number 14: 21; copy number 15: 25; copy number 17: 5; copy number 20: 72; copy number 21: 13; copy number 22: 5; copy number 44: 1; copy number 72: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FJ-01A-11D-A011-01): tumor purity 0.81, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:156,776,020–157,210,779, 6 genes (within-gene range 0–2): ARID1B, AL355297.3, MIR4466, AL355297.1, AL162578.1, AL049820.1.
- chr9:136,807,943–136,841,187, 1 gene (within-gene range 0–2): RABL6.
- chr9:136,830,957–136,926,607, 7 genes (within-gene range 0–2): MIR4292, AJM1, PHPT1, MAMDC4, EDF1, TRAF2, MIR4479.
- chr15:49,794,246–50,236,385, 6 genes: AC025040.2, ATP8B4, AC025040.1, RNA5SP394, SLC27A2, Y_RNA.
- chr15:50,244,628–50,244,931, 1 gene: RN7SL494P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 448 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,533,383–67,278,779, 16 genes, copy number 9–17: SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1, SLC35D1, C1orf141, AL133320.1, AL133320.2, IL23R, RNU6-586P, RNU4ATAC4P, DNAJB6P4.
- chr1:172,532,349–172,666,876, 3 genes, copy number 9: SUCO, RNU6-693P, FASLG.
- chr1:223,538,007–224,437,033, 27 genes, copy number 10: CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742.
- chr2:229,606,238–229,702,148, 2 genes, copy number 10: RNU7-9P, AC007559.1.
- chr6:1,321,698–1,613,897, 9 genes, copy number 9: LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:19,323,428–19,839,080, 1 gene, copy number 11 (within-gene range 4–11): LNC-LBCS.
- chr6:19,438,283–22,654,455, 33 genes, copy number 10–22 (within-gene range 4–22): RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1.
- chr6:71,450,834–71,458,874, 1 gene, copy number 10: LINC01626.
- chr8:126,556,323–127,419,050, 1 gene, copy number 10 (within-gene range 4–10): PCAT1.
- chr8:127,072,694–127,742,951, 12 genes, copy number 10: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 10: MIR1204.
- chr11:34,335,118–35,818,007, 26 genes, copy number 9–15 (within-gene range 6–15): MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44.
- chr11:36,269,284–36,697,867, 11 genes, copy number 9: COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr12:8,681,600–16,992,083, 240 genes, copy number 9–72 (within-gene range 4–72) (broad region; genes not listed).
- chr17:41,377,650–41,640,199, 22 genes, copy number 12–14: KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P.
- chr17:41,730,127–41,730,405, 1 gene, copy number 9: RN7SL399P.
- chr19:13,731,760–14,075,062, 27 genes, copy number 9: CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199.
- chr22:49,757,627–49,964,072, 15 genes, copy number 15: RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
